Gene-level copy-number profile of tumor specimen ALCH-AE1Q-TTP1-A from ALCHEMIST case ALCH-AE1Q, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 64.3 years (23,478 days).
Specimen ALCH-AE1Q-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 29e87fa8-4edc-454b-9622-f0953022336f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AE1Q-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/206dc87d-e648-4d6d-a7d4-6c73207362d2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 36; copy number 1: 13,656; copy number 2: 37,732; copy number 3: 5,285; copy number 4: 950; copy number 5: 658; copy number 6: 30; copy number 7: 1; copy number 19: 1; copy number 20: 1; copy number 21: 3; copy number 22: 21; copy number 23: 19; copy number 40: 6.

Homozygous deletions (total copy number 0; autosomes only): 35 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,915,108–1,919,279, 2 genes: CALML6, TMEM52.
- chr2:124,680,722–124,680,916, 1 gene (within-gene range 0–1): MTND5P22.
- chr2:140,683,360–140,683,888, 1 gene (within-gene range 0–1): COPRSP1.
- chr2:240,868,824–240,880,502, 1 gene: AGXT.
- chr4:181,064,089–181,523,001, 4 genes: LINC00290, AC019235.1, LINC02500, AC093840.1.
- chr4:184,254,509–184,255,330, 1 gene: AC079080.1.
- chr5:92,889,387–92,890,840, 1 gene: CCT7P2.
- chr7:1,508,655–1,509,427, 1 gene: AC093734.1.
- chr7:45,789,585–45,821,064, 4 genes: RNU6-241P, CICP20, AC096582.1, AC096582.2.
- chr8:3,700,492–3,700,628, 1 gene (within-gene range 0–1): RNA5SP251.
- chr8:22,024,125–22,036,897, 1 gene: NPM2.
- chr8:27,490,781–27,545,564, 1 gene: EPHX2.
- chr8:33,473,386–33,523,291, 4 genes (within-gene range 0–1): TTI2, MAK16, SNORD13, AC091144.1.
- chr9:136,949,551–136,955,497, 1 gene (within-gene range 0–1): LCN12.
- chr13:19,152,567–19,187,618, 4 genes: SMPD4P2, AL139327.3, TUBA3C, AL139327.1.
- chr17:81,461,013–81,461,937, 1 gene (within-gene range 0–2): AC110285.4.
- chr19:52,064,466–52,110,726, 2 genes (within-gene range 0–1): ZNF841, AC011468.4.
- chr20:34,990,376–34,990,497, 2 genes (within-gene range 0–2): MIR499A, MIR499B.
- chr22:18,873,543–18,894,407, 2 genes: FAM230F, AC008103.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 740 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,681,249–248,748,349, 1 gene, copy number 6 (within-gene range 3–6): CR589904.2.
- chr1:248,691,760–248,864,796, 10 genes, copy number 6: LYPD9P, CR589904.1, AHCYP8, LYPD8, DPY19L4P1, SH3BP5L, MIR3124, ZNF672, ZNF692, AL672291.1.
- chr3:172,039,578–198,123,232, 512 genes, copy number 5 (broad region; genes not listed).
- chr8:7,190,901–7,191,563, 1 gene, copy number 7: RPS3AP33.
- chr8:37,326,575–39,105,445, 63 genes, copy number 5 (broad region; genes not listed).
- chr9:32,676,063–33,402,682, 22 genes, copy number 5: SNRPCP1, AL157884.1, TMEM215, Y_RNA, AL157884.3, AL157884.2, APTX, BOLA3P4, ASS1P12, TCEA1P4, LAGE3P1, DNAJA1, SMU1, B4GALT1, B4GALT1-AS1, RNU4ATAC15P, SPINK4, BAG1, CHMP5, NFX1, Y_RNA, AQP7.
- chr10:79,892,148–79,893,175, 1 gene, copy number 5: PGGT1BP2.
- chr10:87,341,685–87,370,695, 2 genes, copy number 5–6 (within-gene range 2–6): LINC00863, NUTM2D.
- chr11:61,588,442–61,747,001, 4 genes, copy number 19–21 (within-gene range 2–21): AP002754.1, RPLP0P2, AP002754.2, DAGLA.
- chr11:68,980,021–70,436,584, 46 genes, copy number 22–40: MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr14:25,647,304–26,143,305, 1 gene, copy number 6 (within-gene range 3–6): LINC02306.
- chr14:25,916,015–28,490,362, 17 genes, copy number 6: AL132633.1, CYB5AP5, NOVA1, AL079343.1, LINC02588, AL110292.1, LINC02294, LINC02293, AL132718.1, MIR4307HG, MIR4307, AL390334.1, LINC00645, MIR3171, BNIP3P1, AL139023.1, RPL26P3.
- chr14:31,420,286–31,488,039, 4 genes, copy number 5 (within-gene range 4–5): AL139353.2, DTD2, AL163973.1, GPR33.
- chr14:35,538,352–38,194,281, 48 genes, copy number 5 (within-gene range 2–5): RALGAPA1, AL137818.1, QRSL1P3, AL162311.3, NUTF2P2, BRMS1L, AL162311.1, AL162311.2, AL133304.3, AL133304.1, ILF2P2, AL133304.2, LINC00609, PTCSC3, AL162511.1, RN7SKP21, MBIP, AL132857.1, DPPA3P2, RNU7-93P, SFTA3, SFTA3, NKX2-1, NKX2-1-AS1, PHKBP2, RPL29P3, NKX2-8, RN7SKP257, AL079303.1, PAX9, SLC25A21, AL162464.2, AL162464.1, MIR4503, AL079304.1, SLC25A21-AS1, RNU6-273P, MIPOL1, RNU6-886P, AL121790.2, AL121790.1, FOXA1, TTC6, AL136296.1, RNU6-1277P, LINC00517, AL359233.1, AL392023.2.
- chr22:21,103,016–21,128,063, 3 genes, copy number 5: BCRP2, AP000550.1, POM121L7P.
- chr22:21,193,360–21,268,903, 4 genes, copy number 5: FAM247A, GGT2, AP000550.3, E2F6P3.
- chr22:21,354,563–21,358,067, 1 gene, copy number 20: LINC01651.

Autosomal genes at a single copy (total copy number 1): 12,076. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
